CGCI case HTMCP-02-28-01225 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17722bc1-b7b7-4e04-9c94-4137001ceb2c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 69.9 years (25,514 days); Year of diagnosis: 2017; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 896 days (2.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 210 days; Disease response: Tumor Free.
- Days to follow up: 588 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 896 days (2.5 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -8,073.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day -8,073: Comorbidities: HIV/AIDS.
- Day -8,073: Risk factors: HIV/AIDS.
- Day 0: Haart treatment indicator: Yes; HIV viral load: 20.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 22; Tobacco smoking quit year: 1995.

Biospecimens (3 samples)
- Sample HTMCP-02-28-01225-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-28-01225-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-28-01225-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Squamous Cell Carcinoma, Not Otherwise Specified; Tumor status: Tumor free; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 3; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Primary pathology: Method initial path diagnosis: Fine needle aspiration biopsy.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-28-01225-01A-01E-13790:
- % tumour top: 80
- % tumour bottom: 80

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-28-01225-01A-01S-13790:
- % tumour top: 80
- % tumour bottom: 80
